TCGA case TCGA-G2-A2EJ — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c6227d39-d9e8-4e28-9e70-d7f720ab25e4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,649 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,460 days (4.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Ifosfamide + Paclitaxel; Days to treatment start: 38 days; Days to treatment end: 38 days; Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Mesna; Days to treatment start: 38 days; Days to treatment end: 38 days; Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lung, NOS. Age at diagnosis: 59.0 years (21,559 days); Days to diagnosis: 910 days (2.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 806 days (2.2 years); Disease response: Tumor Free.
- Day 910 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 910 days (2.5 years).
- Days to follow up: 931 days (2.5 years); Disease response: With Tumor.
- Days to follow up: 1,460 days (4.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65.3 kg; Height: 152.4 cm; BMI: 28.1.

Exposures
- Occupation type: Manufacturing Labourers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Age at onset: 27.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G2-A2EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-G2-A2EJ-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-G2-A2EJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G2-A2EJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: retired factory worker; Occupation primary: factory worker; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Incidental prostate cancer indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Drug treatment 2: Pharmaceutical therapy drug name: Mesna; Clinical trial drug classification: Chemoprotectant.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,460 days; disease-specific survival: no event (censored), 1,460 days; disease-free interval: event (new tumor event after initially disease-free), 910 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 910 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G2-A2EJ-01A-11D-A17S-01): tumor purity 0.61, ploidy 2.09, whole-genome doublings 0.
